Somatic mutation profile of tumor specimen TARGET-40-NAAECZ-01A (aliquot TARGET-40-NAAECZ-01A-01D) from TARGET case TARGET-40-NAAECZ, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 20.0 years (7,311 days).
Specimen TARGET-40-NAAECZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f86793db-e169-4d99-83ab-1f5220b517fb.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAECZ-10A (Blood Derived Normal), aliquot TARGET-40-NAAECZ-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9e250afa-a76c-4272-9294-128abee65538

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.796G>A p.G266R | Missense Mutation (SNP) | VAF 54/105 reads (51%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs1057519990, COSV52670619, COSV52672762, COSV52751844; ClinVar: pathogenic / likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- PXN | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.226); catalogued as rs1481882940; called by muse, mutect2, varscan2
- ATP1A3 | c.1540C>A p.P514T (on ENST00000545399 / NM_001256214.2; = p.P501T on NM_152296.5) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KRT26 | c.27C>G p.S9= | Silent (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
